Somatic mutation profile of tumor specimen TCGA-CH-5789-01A (aliquot TCGA-CH-5789-01A-11D-1576-08) from TCGA case TCGA-CH-5789, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.6 years (22,494 days).
Specimen TCGA-CH-5789-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4d34f75-75ee-4ca7-b6bf-bf5f4ee43892.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5789-10A (Blood Derived Normal), aliquot TCGA-CH-5789-10A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e57767c-9840-49b7-a989-e68459f7ab21

The open-access MAF lists 1 somatic variant for this specimen: 1 silent.
By variant classification: Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MUC16 | c.11613G>A p.E3871= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as rs867613747, COSV67465042; called by muse, mutect2
